Somatic mutation profile of tumor specimen TCGA-77-A5G3-01A (aliquot TCGA-77-A5G3-01A-31D-A27K-08) from TCGA case TCGA-77-A5G3, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 63.4 years (23,171 days).
Specimen TCGA-77-A5G3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ac43221-edb9-44bb-b4a4-8d35b75dadd2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-A5G3-10A (Blood Derived Normal), aliquot TCGA-77-A5G3-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3505e5e1-4811-4430-b882-03e6bd984d3e

The open-access MAF lists 681 somatic variants for this specimen: 506 protein-altering or splice-affecting, 157 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 431, Silent 157, Nonsense Mutation 34, Frame Shift Del 16, Frame Shift Ins 9, Intron 7, Splice Site 6, RNA 6, Splice Region 5, In Frame Del 3, 5'UTR 3, Translation Start Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 13/23 reads (57%) | hotspot (GDC flag); catalogued as rs121913384, CM034218, CM095540, COSV58683071, COSV58683670; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PC | c.1892G>A p.R631Q | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113994145, CM092836, COSV67369483; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 16/35 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- TP53 | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- A1CF | c.618A>T p.L206F | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as COSV99255348; called by muse, mutect2, varscan2
- A1CF | c.294T>G p.Y98* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV99255349; called by muse, mutect2, varscan2
- ABCA13 | c.10024G>A p.D3342N | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV101446833; called by muse, mutect2
- ABCB1 | c.3001G>A p.A1001T | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1213524837, COSV99712270; called by muse, mutect2, varscan2
- ABCB11 | c.1476G>C p.Q492H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV99791611; called by muse, mutect2, varscan2
- ABCC11 | c.1645G>C p.G549R | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100750570, COSV100750611; called by muse, mutect2, varscan2
- ABCC9 | c.343A>T p.T115S | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV99684679, COSV99684870; called by muse, mutect2, varscan2
- AC011479.1 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100007805; called by muse, mutect2
- ACAN | c.6670C>A p.Q2224K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs765299489, COSV100717187; called by muse, mutect2, varscan2
- ACSL6 | c.1543G>A p.V515M (on ENST00000379240; = p.V540M on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs372695315; called by muse, mutect2, varscan2
- ACTB | c.433T>C p.S145P | Missense Mutation (SNP) | VAF 43/220 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV100079406; called by muse, mutect2, varscan2
- ACTC1 | c.593G>C p.R198P | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.416); catalogued as COSV51760101, COSV99291629; called by muse, mutect2, varscan2
- ACTR6 | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99498504; called by muse, mutect2, varscan2
- ADAD1 | c.1358A>G p.H453R | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV99635155; called by muse, mutect2, varscan2
- ADAM11 | c.2057G>T p.C686F | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99567147; called by muse, mutect2
- ADAMTS12 | c.1540G>T p.A514S | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100710357; called by muse, mutect2
- ADAMTS16 | c.1558T>A p.W520R | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99940213; called by muse, mutect2, varscan2
- ADAMTS17 | c.2069G>T p.G690V | Missense Mutation (SNP) | VAF 20/243 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99170347, COSV99170393; called by muse, mutect2
- ADCY4 | c.978T>A p.C326* | Nonsense Mutation (SNP) | VAF 13/62 reads (21%) | catalogued as COSV100156217; called by muse, mutect2, varscan2
- ADGRB3 | c.1486G>T p.G496C | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs766589399, COSV100999971; called by muse, mutect2, varscan2
- AFG3L2 | c.1474C>T p.R492* | Nonsense Mutation (SNP) | VAF 13/75 reads (17%) | catalogued as rs753902034, COSV99301548; called by muse, mutect2, varscan2
- AHCTF1 | c.5036C>T p.A1679V (on ENST00000366508; = p.A1653V on NM_015446.5) | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100403180; called by muse, mutect2, varscan2
- AK5 | c.673G>A p.A225T (on ENST00000354567 / NM_174858.3; = p.A199T on NM_012093.4) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.848); catalogued as COSV100481364; called by muse, mutect2, varscan2
- AKAP11 | c.2348C>T p.P783L | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99213565; called by muse, mutect2, varscan2
- ALLC | c.836C>A p.T279K | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99377567; called by muse, mutect2, varscan2
- AMACR | c.157C>A p.L53I | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.163); catalogued as COSV100162832; called by muse, mutect2
- AMER2 | c.1430G>C p.R477T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.678); catalogued as COSV100766144; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7100C>A p.P2367Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99782229; called by muse, mutect2, varscan2
- ANKRD34B | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV100103383; called by muse, mutect2, varscan2
- ANKRD44 | c.2639C>T p.A880V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV99984224; called by muse, mutect2, varscan2
- ANO3 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.165); catalogued as rs1463437940, COSV56781821; called by muse, mutect2, varscan2
- ARAF | c.306A>G p.V102= | Splice Region (SNP) | VAF 22/44 reads (50%) | catalogued as COSV99282994; called by muse, mutect2, varscan2
- ARAP3 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.063); catalogued as rs1366653010, COSV99499365; called by muse, mutect2, varscan2
- ARHGAP29 | c.183T>A p.Y61* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as COSV99557703; called by muse, mutect2, varscan2
- ARHGAP36 | c.1231T>A p.S411T | Missense Mutation (SNP) | VAF 78/163 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.804); catalogued as COSV99357306; called by muse, mutect2, varscan2
- ARHGEF17 | c.4300A>G p.T1434A | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.137); catalogued as rs369247751; called by muse, mutect2, varscan2
- ARRDC1 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as rs138785809; called by muse, mutect2
- ASCC3 | c.4786-1G>C p.X1596_splice | Splice Site (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100976253; called by muse, mutect2, varscan2
- ATF7 | c.679C>G p.P227A (on ENST00000548446 / NM_001366555.2; = p.P216A on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.326); catalogued as COSV100129028, COSV100129197; called by muse, mutect2, varscan2
- ATF7IP | c.3447G>T p.Q1149H | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.794); catalogued as COSV99661244, COSV99662076; called by muse, mutect2, varscan2
- ATP5MC2 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100100947; called by muse, mutect2
- ATP6V0A2 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 23/140 reads (16%) | catalogued as COSV100376845; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1343G>A p.G448E | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100022733; called by muse, mutect2, varscan2
- ATP6V1C1 | c.1000G>C p.V334L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV101214849; called by muse, mutect2, varscan2
- ATP8B4 | c.1090T>C p.Y364H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99463999; called by muse, mutect2
- ATR | c.5232A>T p.L1744F | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100637722; called by muse, mutect2, varscan2
- ATR | c.5123A>G p.E1708G | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV100637723; called by muse, mutect2
- B4GALT1 | c.939_941del p.E313del | In Frame Del (DEL) | VAF 14/52 reads (27%) | catalogued as rs749067079; called by pindel, varscan2
- BAZ2A | c.193A>G p.T65A | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs1487876135, COSV99464841; called by muse, mutect2
- BCL9L | c.2227G>T p.G743C | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.869); catalogued as COSV99418730; called by muse, mutect2, varscan2
- BMP5 | c.986C>G p.S329C | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV100895786; called by muse, mutect2, varscan2
- BMX | c.1439C>G p.S480* | Nonsense Mutation (SNP) | VAF 17/99 reads (17%) | catalogued as COSV100564317; called by muse, mutect2, varscan2
- BRCA1 | c.4315C>T p.L1439F | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as rs781260818, COSV58802364; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- BRINP1 | c.2164T>A p.C722S | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99774595; called by muse, mutect2, varscan2
- BRINP3 | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100818417, COSV100819618; called by muse, mutect2
- BRWD3 | c.4160C>T p.P1387L | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100955694; called by muse, mutect2, varscan2
- BTN3A3 | c.1592C>T p.S531F | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.144); catalogued as COSV55072164; called by muse, mutect2
- C1QTNF3 | c.599A>T p.K200I | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV99180685; called by muse, mutect2, varscan2
- C7 | c.1962G>T p.K654N | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100495464; called by muse, mutect2, varscan2
- CACNA1A | c.3361C>A p.Q1121K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.114); catalogued as COSV100801172; called by muse, mutect2, varscan2
- CADM3 | c.263C>A p.S88Y (on ENST00000368125 / NM_001127173.3; = p.S122Y on NM_021189.5) | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV100930265; called by muse, mutect2, varscan2
- CALN1 | c.40G>T p.G14W (on ENST00000329008 / NM_001017440.3; = p.G56W on NM_031468.4) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100205157, COSV61149726; called by muse, mutect2, varscan2
- CASD1 | c.661A>T p.R221W | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51971558, COSV99802321; called by muse, mutect2
- CASD1 | c.1715G>A p.G572D | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.076); catalogued as rs1562949074, COSV99802325; called by muse, mutect2
- CCDC102B | c.1090G>C p.D364H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as COSV100102389; called by muse, varscan2
- CCDC144A | c.2698G>T p.E900* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100138394; called by muse, varscan2
- CCNA2 | c.1208A>G p.Q403R | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as COSV99696770; called by muse, mutect2, varscan2
- CCR1 | c.109C>A p.L37M | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs201648654, COSV99946652; called by muse, mutect2, varscan2
- CCSER1 | c.1849G>A p.D617N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV100388412, COSV61446193; called by muse, mutect2, varscan2
- CCSER2 | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV99825523; called by muse, mutect2, varscan2
- CD163L1 | c.144G>C p.L48F | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as rs760126235, COSV100549747; called by muse, mutect2, varscan2
- CD69 | c.124C>A p.L42M | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as COSV99945982; called by muse, mutect2, varscan2
- CD8B | c.196C>T p.H66Y | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as COSV100514385; called by muse, mutect2, varscan2
- CDH10 | c.1511G>T p.G504V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100050252; called by muse, varscan2
- CDK14 | c.1063G>A p.D355N (on ENST00000380050 / NM_001287135.2; = p.D337N on NM_012395.3) | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.183); catalogued as COSV56049543; called by muse, mutect2, varscan2
- CEACAM18 | c.491C>G p.T164S | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.042); catalogued as COSV101140184; called by muse, mutect2, varscan2
- CELF2 | c.989C>A p.A330E (on ENST00000416382 / NM_001025077.3; = p.A337E on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as COSV100256843; called by muse, mutect2, varscan2
- CEP170B | c.2932C>A p.Q978K (on ENST00000453495; = p.Q907K on NM_015005.3) | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.012); catalogued as COSV101371408; called by muse, mutect2, varscan2
- CEP192 | c.7367C>T p.S2456L | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV58071406; called by muse, mutect2, varscan2
- CEP250 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as COSV100698767; called by muse, mutect2, varscan2
- CEP290 | c.3912G>A p.M1304I | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV100467937; called by muse, mutect2
- CEP63 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV100132587; called by muse, mutect2, varscan2
- CFAP47 | c.5515G>A p.D1839N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.025); catalogued as COSV100545003; called by muse, mutect2, varscan2
- CLDN8 | c.191G>A p.C64Y | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99729686; called by muse, mutect2, varscan2
- CNGA4 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs773908561, COSV66005104; called by muse, varscan2
- CNTN6 | c.424C>A p.L142I | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.263); catalogued as COSV100610157; called by muse, mutect2, varscan2
- CNTNAP2 | c.2016A>G p.I672M | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100663250; called by muse, mutect2, varscan2
- COL24A1 | c.1630G>A p.G544S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as rs757253847, COSV100992948; called by muse, mutect2
- COL4A2 | c.1453T>C p.C485R | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369804330; called by muse, mutect2, varscan2
- COL5A3 | c.2165G>A p.G722D | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99318293; called by muse, mutect2, varscan2
- COL7A1 | c.8610G>T p.W2870C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.417); catalogued as COSV99866129; called by muse, mutect2, varscan2
- COMMD2 | c.412A>T p.R138* | Nonsense Mutation (SNP) | VAF 19/135 reads (14%) | catalogued as COSV101519911; called by muse, mutect2, varscan2
- COPA | c.2569G>T p.G857W | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99614755; called by muse, mutect2, varscan2
- COPS4 | c.1175C>G p.A392G | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100018381; called by muse, mutect2, varscan2
- CORIN | c.3011C>G p.T1004S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV99903020; called by muse, mutect2, varscan2
- CORIN | c.362G>T p.W121L | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV99903021; called by muse, mutect2
- CPNE4 | c.1588C>A p.Q530K | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV101456588; called by muse, mutect2, varscan2
- CPNE8 | c.1036G>T p.A346S | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.951); catalogued as COSV100503989; called by muse, mutect2, varscan2
- CRLF2 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs1214618261, COSV101053613; called by muse, mutect2, varscan2
- CSMD1 | c.3754C>G p.H1252D (on ENST00000520002; = p.H1251D on NM_033225.6) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV100144478; called by muse, mutect2, varscan2
- CSMD1 | c.2080G>T p.G694C (on ENST00000520002; = p.G693C on NM_033225.6) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100144480; called by muse, mutect2
- CSMD3 | c.4202G>T p.R1401M (on ENST00000297405 / NM_001363185.1; = p.R1297M on NM_052900.3) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV52346033; called by muse, mutect2, varscan2
- CSMD3 | c.1537G>T p.D513Y (on ENST00000297405 / NM_001363185.1; = p.D409Y on NM_052900.3) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99826252; called by muse, mutect2, varscan2
- CSN3 | c.275A>T p.Q92L | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100515266; called by muse, mutect2
- CSRNP3 | c.519C>A p.F173L | Missense Mutation (SNP) | VAF 60/237 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100085205; called by muse, mutect2, varscan2
- CTNNA2 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.024); catalogued as rs1451882176, COSV63544327; called by muse, mutect2
- CTTN | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100097204; called by muse, mutect2, varscan2
- DAG1 | c.1667G>A p.S556N | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); catalogued as COSV100444740; called by muse, mutect2, varscan2
- DCAF4L2 | c.991G>T p.A331S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.583); catalogued as COSV100150534; called by muse, mutect2, varscan2
- DCANP1 | c.433A>T p.T145S | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.533); catalogued as COSV101538215; called by muse, mutect2, varscan2
- DCC | c.605T>A p.L202H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); catalogued as COSV100498469; called by muse, mutect2, varscan2
- DCC | c.1006C>G p.H336D | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.228); catalogued as COSV100498471, COSV59117984; called by muse, mutect2, varscan2
- DCC | c.1517A>G p.N506S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); catalogued as rs1158853961, COSV100498472; called by muse, mutect2, varscan2
- DCDC1 | c.3259C>A p.P1087T (on ENST00000597505 / NM_001367979.1; = p.P194T on NM_020869.3) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100337890, COSV60304143; called by muse, mutect2, varscan2
- DCSTAMP | c.786G>C p.Q262H | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV99886130; called by muse, mutect2
- DDR1 | c.1576G>T p.G526C | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.669); catalogued as COSV100241074; called by muse, mutect2, varscan2
- DDX3X | c.1277A>C p.K426T (on ENST00000399959; = p.K427T on NM_001356.5) | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV101302353; called by muse, mutect2, varscan2
- DEFB136 | c.182G>T p.C61F | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101198591; called by muse, mutect2
- DGKD | c.2200G>T p.G734C (on ENST00000264057 / NM_152879.3; = p.G690C on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.363); catalogued as rs145038453, COSV99895522; called by muse, mutect2, varscan2
- DIP2B | c.533C>G p.S178* | Nonsense Mutation (SNP) | VAF 9/117 reads (8%) | catalogued as COSV56587407; called by muse, mutect2
- DLGAP2 | c.964C>G p.P322A | Missense Mutation (SNP) | VAF 21/207 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.108); catalogued as rs778052783, COSV101421103, COSV101421803; called by muse, mutect2
- DMBT1 | c.5229G>T p.Q1743H (on ENST00000338354 / NM_001377530.1; = p.Q986H on NM_004406.3) | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as COSV100352248; called by muse, mutect2, varscan2
- DNAH5 | c.8525G>T p.W2842L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV99445642, COSV99448797; called by muse, mutect2, varscan2
- DNAH5 | c.6923C>G p.A2308G | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV99445649; called by muse, mutect2, varscan2
- DNAH5 | c.6164G>T p.C2055F | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99445650; called by muse, mutect2
- DNAH7 | c.8524C>T p.Q2842* | Nonsense Mutation (SNP) | VAF 21/217 reads (10%) | catalogued as rs375780815; called by muse, mutect2
- DNMT3L | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.262); catalogued as COSV99533175; called by muse, mutect2, varscan2
- DOCK4 | c.297G>T p.M99I | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV101455456; called by muse, mutect2, varscan2
- DOCK8 | c.260C>T p.T87I | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV101210190; called by muse, mutect2, varscan2
- DPY19L2 | c.1307G>T p.G436V | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV100116560; called by muse, mutect2, varscan2
- DRGX | c.86T>C p.L29P | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.756); catalogued as COSV100938299; called by muse, mutect2
- DYRK4 | c.1163G>T p.R388L | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99155451; called by muse, mutect2, varscan2
- EEF2 | c.1517G>T p.R506I | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100500583; called by muse, mutect2, varscan2
- EIF2S1 | c.797G>T p.R266M | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as rs1252924259, COSV53606870; called by muse, mutect2
- ELP4 | c.967G>A p.D323N (on ENST00000350638; = p.D322N on NM_019040.5) | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766767508, COSV100635887, COSV63353770, COSV63356244; called by muse, mutect2
- EPB41L3 | c.715G>T p.D239Y | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100548239, COSV100549886; called by muse, mutect2
- ERC1 | c.1880G>T p.R627L (on ENST00000360905 / NM_178040.4; = p.R599L on NM_178039.4) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV100705657; called by muse, mutect2, varscan2
- EVA1C | c.477A>C p.Q159H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV100291186; called by muse, mutect2, varscan2
- EYS | c.19G>T p.V7F | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.042); catalogued as COSV100675758; called by muse, mutect2, varscan2
- F13B | c.1432C>T p.H478Y | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100803198; called by muse, mutect2, varscan2
- FAAH2 | c.1038A>T p.Q346H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV100887169; called by muse, mutect2, varscan2
- FAM111B | c.2075G>A p.C692Y | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.189); catalogued as COSV100639238; called by muse, mutect2, varscan2
- FAM120A | c.1442G>T p.G481V | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as COSV99464619; called by muse, mutect2, varscan2
- FAM124B | c.671T>C p.M224T | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs199522881, COSV99706238; called by muse, mutect2, varscan2
- FAM221B | c.719C>A p.A240E | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs764042708, COSV100941301; called by muse, mutect2, varscan2
- FBLN2 | c.1595G>T p.G532V | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99851484; called by muse, mutect2, varscan2
- FBLN5 | c.946G>T p.D316Y | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.552); catalogued as COSV50902297, COSV99969376; called by muse, mutect2, varscan2
- FBN3 | c.3097C>A p.R1033S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.168); catalogued as COSV99560013; called by muse, mutect2, varscan2
- FBXL16 | c.1259C>T p.A420V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV99556357; called by muse, mutect2, varscan2
- FCRL2 | c.1394-2A>T p.X465_splice | Splice Site (SNP) | VAF 18/83 reads (22%) | catalogued as COSV100829839; called by muse, mutect2, varscan2
- FCRL4 | c.52G>C p.A18P | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as COSV54862700, COSV54865903, COSV99619349; called by muse, mutect2, varscan2
- FEM1C | c.1444A>T p.N482Y | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99174349; called by muse, mutect2, varscan2
- FERD3L | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99284735; called by muse, mutect2, varscan2
- FERMT3 | c.618C>G p.D206E | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV99656343; called by muse, mutect2, varscan2
- FLCN | c.1682A>T p.Y561F | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV99550149; called by muse, mutect2, varscan2
- FLG | c.8626G>A p.G2876R | Missense Mutation (SNP) | VAF 35/822 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.125); catalogued as rs1178753038, COSV64252906; called by muse, mutect2
- FN1 | c.1412C>A p.T471K | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100116257; called by muse, mutect2, varscan2
- FPGS | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs771725616, COSV64676069; called by muse, mutect2, varscan2
- FPR2 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100389141; called by muse, mutect2, varscan2
- FREM1 | c.4507G>T p.D1503Y | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101083893; called by muse, mutect2, varscan2
- FSCB | c.599C>A p.P200Q | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61216684; called by muse, mutect2
- FSHR | c.725A>T p.K242M | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100436633; called by muse, mutect2, varscan2
- FSIP2 | c.17789C>A p.S5930Y | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100554192; called by muse, mutect2, varscan2
- FSTL5 | c.321C>G p.F107L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as COSV100053115, COSV60187786; called by muse, mutect2, varscan2
- FTCD | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99384698; called by muse, mutect2, varscan2
- GALNT17 | c.1094G>T p.G365V | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100352538, COSV61182193; called by muse, mutect2, varscan2
- GALNTL6 | c.186T>A p.D62E | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV101560141; called by muse, mutect2, varscan2
- GALNTL6 | c.1110C>A p.Y370* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as COSV101560142, COSV72489031; called by muse, mutect2, varscan2
- GAS2L3 | c.1447G>C p.D483H | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV99902705; called by muse, mutect2, varscan2
- GCM1 | c.1293C>A p.N431K | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV99452145; called by muse, mutect2, varscan2
- GIMAP2 | c.704G>C p.R235T | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV99785226; called by muse, mutect2, varscan2
- GPAA1 | c.1667C>T p.T556M | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as rs375812008; called by muse, mutect2, varscan2
- GPC5 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.053); catalogued as rs559277707, COSV65579895; called by muse, mutect2, varscan2
- GPR141 | c.493C>A p.H165N | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.012); catalogued as COSV100550240; called by muse, mutect2, varscan2
- GRB14 | c.1399G>C p.D467H | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99813706; called by muse, mutect2, varscan2
- GRID1 | c.2491T>C p.F831L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV100022198; called by mutect2, varscan2
- GRIK2 | c.317T>C p.I106T | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV100023531; called by muse, mutect2, varscan2
- GRM1 | c.889C>G p.R297G | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV51114809, COSV99264364; called by mutect2, varscan2
- GRM8 | c.2429A>T p.K810M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100281061; called by muse, mutect2, varscan2
- GTF3C4 | c.1223A>T p.K408I | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as COSV100935911; called by muse, mutect2, varscan2
- GTPBP2 | c.1136G>A p.G379E | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100199851; called by muse, mutect2, varscan2
- GULP1 | c.305C>A p.A102E | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100770274; called by muse, mutect2, varscan2
- GYG2 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100088735; called by muse, mutect2, varscan2
- H4C8 | c.153C>G p.I51M | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs761771008, COSV99175455; called by muse, mutect2, varscan2
- HARS2 | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs779525996, COSV99217984; called by muse, mutect2, varscan2
- HCN1 | c.1604G>C p.G535A | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100298822; called by muse, mutect2, varscan2
- HERC1 | c.4954G>C p.E1652Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV101496374; called by muse, mutect2, varscan2
- HERC2 | c.287C>G p.S96* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV99871368; called by muse, mutect2, varscan2
- HIGD1B | c.272G>A p.R91K | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1189796007, COSV53656585; called by muse, mutect2
- HIVEP3 | c.4541C>G p.P1514R | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV99911623; called by muse, mutect2, varscan2
- HLA-E | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100931882, COSV64927401; called by muse, mutect2, varscan2
- HPD | c.180T>A p.H60Q | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as COSV100000032; called by muse, mutect2, varscan2
- HS3ST2 | c.434C>A p.T145K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as COSV99757696; called by muse, mutect2, varscan2
- HTATSF1 | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99511411; called by muse, mutect2, varscan2
- HTR1B | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as rs1440772703, COSV100885342; called by muse, mutect2, varscan2
- HTR1F | c.1007G>C p.G336A | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100137971; called by muse, mutect2, varscan2
- HTRA4 | c.787C>A p.L263M | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100205602; called by muse, mutect2, varscan2
- IFNA16 | c.342G>C p.Q114H | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV101207056; called by muse, mutect2, varscan2
- IGKV1-16 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 8/128 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.076); catalogued as rs1420833827; called by muse, mutect2
- IGKV2D-29 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.334); catalogued as COSV101534362; called by muse, mutect2, varscan2
- IGSF1 | c.72G>A p.R24= | Splice Region (SNP) | VAF 14/39 reads (36%) | catalogued as rs1182900802, COSV100811853; called by muse, mutect2, varscan2
- IKZF3 | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); catalogued as rs574227572, COSV99499276; called by muse, mutect2, varscan2
- IL1RAPL1 | c.335A>G p.D112G | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759718387, COSV100145414; called by muse, mutect2, varscan2
- INCENP | c.2360G>A p.S787N (on ENST00000394818 / NM_001040694.2; = p.S783N on NM_020238.3) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99610713; called by muse, mutect2
- IRX5 | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV100315646; called by muse, mutect2, varscan2
- JAK3 | c.2684G>A p.R895H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV71686228; called by muse, mutect2, varscan2
- KALRN | c.3520T>A p.Y1174N | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99562412; called by muse, mutect2, varscan2
- KALRN | c.3692G>C p.R1231P | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53776131, COSV99562417; called by muse, mutect2, varscan2
- KCNB2 | c.1117T>G p.W373G | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101578682, COSV73051130; called by muse, mutect2, varscan2
- KCNJ3 | c.30C>A p.D10E | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54539401, COSV99715328; called by muse, mutect2, varscan2
- KCNQ3 | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1479652323, COSV66467913, COSV66472703; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIAA0319L | c.393A>T p.L131F | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as rs41310436, COSV57843171, COSV57844099; called by muse, mutect2, varscan2
- KIAA1210 | c.3118G>T p.V1040F | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV101273937, COSV101274154; called by muse, mutect2, varscan2
- KIDINS220 | c.2790G>A p.W930* | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | catalogued as COSV99875069; called by muse, mutect2, varscan2
- KIFC2 | c.1016G>T p.R339L | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.323); catalogued as COSV100023564, COSV56763116; called by muse, mutect2, varscan2
- KLHL1 | c.1066G>T p.E356* | Nonsense Mutation (SNP) | VAF 25/45 reads (56%) | catalogued as COSV100917048, COSV64777106; called by muse, mutect2, varscan2
- KLHL14 | c.688C>A p.P230T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV100808675, COSV63830818; called by muse, mutect2, varscan2
- KLHL3 | c.45G>T p.Q15H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV100552949; called by muse, mutect2, varscan2
- KLHL4 | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1239104952, COSV100909196; called by muse, mutect2, varscan2
- KMT2C | c.11020G>T p.G3674C | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs1320038786, COSV100067917, COSV51501436; called by muse, mutect2
- KMT2C | c.988C>G p.H330D | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100067920, COSV51487985; called by muse, mutect2
- KMT2D | c.7438A>T p.K2480* | Nonsense Mutation (SNP) | VAF 17/90 reads (19%) | catalogued as COSV99978073; called by muse, mutect2, varscan2
- KNL1 | c.379G>A p.D127N (on ENST00000346991 / NM_170589.5; = p.D101N on NM_144508.5) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.26); catalogued as COSV100706016; called by muse, mutect2
- KRT27 | c.1353_1355del p.N451del | In Frame Del (DEL) | VAF 8/55 reads (15%) | catalogued as rs768288111; called by pindel, varscan2
- LACTB | c.1559C>G p.S520C | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as COSV99978843; called by muse, mutect2, varscan2
- LAMA5 | c.7512-2A>G p.X2504_splice | Splice Site (SNP) | VAF 6/35 reads (17%) | catalogued as rs1306460475, COSV99438311; called by muse, mutect2, varscan2
- LCOR | c.997G>C p.D333H | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100603523; called by muse, mutect2
- LHFPL5 | c.401A>T p.Q134L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV100798933; called by muse, mutect2, varscan2
- LHX6 | c.526G>T p.E176* (on ENST00000373755 / NM_001242334.2; = p.E205* on NM_014368.5) | Nonsense Mutation (SNP) | VAF 31/97 reads (32%) | catalogued as COSV100493237; called by muse, mutect2, varscan2
- LIMS2 | c.307G>T p.E103* (on ENST00000355119 / NM_001161403.3; = p.E127* on NM_017980.4) | Nonsense Mutation (SNP) | VAF 35/180 reads (19%) | catalogued as COSV99760427; called by muse, mutect2, varscan2
- LPAR4 | c.287T>C p.I96T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV101425080; called by muse, mutect2, varscan2
- LRP1B | c.12486G>T p.L4162F | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV101253386, COSV101253676; called by muse, mutect2
- LRRC6 | c.926C>G p.S309C | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as COSV51543184, COSV99137759; called by muse, mutect2
- LRRTM1 | c.547G>C p.D183H | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99701927; called by muse, mutect2, varscan2
- LRRTM4 | c.1150A>T p.I384F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.045); catalogued as COSV101297427; called by muse, mutect2, varscan2
- LZTR1 | c.320G>C p.R107T | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs1301901369, COSV53149285; called by muse, mutect2
- MAB21L2 | c.757G>T p.V253L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100461935; called by muse, mutect2, varscan2
- MAGEB10 | c.684C>A p.N228K | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100775164, COSV63310435; called by muse, mutect2, varscan2
- MAGI1 | c.4112G>T p.R1371I | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV100439566; called by muse, mutect2, varscan2
- MAML3 | c.2131G>T p.V711L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.961); catalogued as COSV101558350; called by muse, mutect2, varscan2
- MAP1LC3C | c.155del p.P52Rfs*13 | Frame Shift Del (DEL) | VAF 16/81 reads (20%) | catalogued as rs762632974, COSV61803913; called by mutect2, pindel, varscan2
- MAP3K19 | c.13C>A p.P5T | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100208145; called by muse, mutect2, varscan2
- MARCO | c.738G>T p.K246N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100503234; called by muse, mutect2
- MBD5 | c.3889C>A p.Q1297K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.04); catalogued as COSV101289959; called by muse, mutect2, varscan2
- MED12L | c.4308G>C p.E1436D | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV99851729; called by muse, mutect2, varscan2
- MMP9 | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.437); catalogued as COSV100959077; called by muse, mutect2, varscan2
- MRGPRX1 | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 5/103 reads (5%) | catalogued as COSV100245875; called by muse, mutect2
- MROH7 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as COSV100272985; called by muse, mutect2, varscan2
- MTMR8 | c.1974G>T p.M658I | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100878319; called by muse, mutect2, varscan2
- MUC17 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.054); catalogued as COSV60281801; called by muse, mutect2
- MUC17 | c.1187C>A p.T396K | Missense Mutation (SNP) | VAF 31/280 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV100071805; called by muse, mutect2, varscan2
- MYCBP2 | c.10816G>A p.E3606K (on ENST00000357337; = p.E3644K on NM_015057.5) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.931); catalogued as COSV62015948; called by muse, mutect2, varscan2
- MYF5 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs768208912, COSV99953135; called by muse, mutect2, varscan2
- MYF6 | c.609A>T p.E203D | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV99952682; called by muse, mutect2, varscan2
- MYH7B | c.5146C>A p.H1716N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV99327866; called by muse, mutect2
- MYH8 | c.3389C>T p.A1130V | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV101238063; called by muse, mutect2, varscan2
- MYLK2 | c.394G>T p.A132S | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as COSV101044670; called by muse, mutect2, varscan2
- MYO6 | c.1618G>C p.D540H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.998); catalogued as COSV100889301, COSV64120759; called by muse, mutect2, varscan2
- MYT1L | c.2330A>G p.K777R | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV101219099, COSV67720321; called by muse, mutect2
- NBEA | c.5116A>T p.T1706S | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV100077205; called by muse, mutect2, varscan2
- NCKAP5 | c.4322G>T p.S1441I | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as COSV100490278; called by muse, mutect2, varscan2
- NCKAP5 | c.524C>G p.T175R | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV100490282; called by muse, mutect2, varscan2
- NCOA1 | c.2813C>A p.S938Y | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99945308; called by muse, mutect2, varscan2
- NDST4 | c.550C>G p.L184V | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.042); catalogued as rs564044682, COSV52131759, COSV52141204, COSV99995081; called by muse, mutect2, varscan2
- NFKB1 | c.1154G>A p.G385E (on ENST00000394820 / NM_001382627.1; = p.G386E on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.172); catalogued as COSV99896716; called by muse, mutect2, varscan2
- NIPBL | c.1408G>C p.E470Q | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV99239063; called by muse, mutect2, varscan2
- NIPBL | c.3283G>T p.D1095Y | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); catalogued as COSV99239067; called by muse, mutect2, varscan2
- NLRP10 | c.1625C>A p.A542E | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.05); catalogued as rs1382393492, COSV100149499, COSV60780541; called by muse, mutect2, varscan2
- NLRP13 | c.1198G>T p.D400Y | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as COSV100738059; called by muse, mutect2, varscan2
- NLRP4 | c.1784A>C p.Y595S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV100015700; called by muse, mutect2
- NPY1R | c.785A>T p.N262I | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99648509; called by muse, mutect2, varscan2
- NRXN3 | c.2351G>T p.R784I (on ENST00000335750 / NM_001330195.2; = p.R411I on NM_004796.6) | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100201150; called by muse, mutect2, varscan2
- NUBPL | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.144); catalogued as COSV99809118; called by muse, mutect2, varscan2
- NUP214 | c.5644G>T p.G1882W | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100845158; called by muse, mutect2, varscan2
- NUP54 | c.1309C>G p.Q437E | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99345163; called by muse, mutect2, varscan2
- OBSCN | c.4159G>A p.G1387R | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs925445808, COSV52758882; called by muse, mutect2
- OBSCN | c.10706G>A p.W3569* | Nonsense Mutation (SNP) | VAF 12/166 reads (7%) | catalogued as rs866606184, COSV99473638; called by muse, mutect2
- OR13G1 | c.654C>G p.I218M | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100687090; called by muse, mutect2
- OR1M1 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs772434948, COSV70036801; called by muse, mutect2, varscan2
- OR2A12 | c.707C>A p.A236D | Missense Mutation (SNP) | VAF 17/201 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs774954746, COSV101283151; called by muse, mutect2
- OR2C3 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100825618; called by muse, mutect2, varscan2
- OR2L8 | c.299G>T p.S100I | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV100594050; called by muse, mutect2, varscan2
- OR2M3 | c.568A>T p.S190C | Missense Mutation (SNP) | VAF 20/221 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV101513397; called by muse, mutect2
- OR2T1 | c.244G>T p.V82F | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs184788541, COSV100822256; called by muse, mutect2
- OR2T12 | c.919G>T p.V307L | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.019); catalogued as COSV100527561; called by muse, mutect2
- OR4A47 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.868); catalogued as rs1565053677, COSV71444855; called by muse, mutect2, varscan2
- OR4E2 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100330023, COSV100330110; called by muse, mutect2, varscan2
- OR4K17 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100210531, COSV100210746; called by muse, mutect2, varscan2
- OR51A2 | c.555T>A p.D185E | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as COSV100985010, COSV66748803; called by muse, mutect2, varscan2
- OR51E2 | c.221C>G p.T74R | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV101211320; called by muse, mutect2, varscan2
- OR51Q1 | c.220G>T p.G74C | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs1425909472, COSV100332821; called by muse, mutect2, varscan2
- OR52D1 | c.810C>G p.H270Q | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.653); catalogued as COSV100495139; called by muse, mutect2, varscan2
- OR52W1 | c.883C>A p.P295T | Missense Mutation (SNP) | VAF 90/294 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as rs746389643, COSV100258593; called by muse, mutect2, varscan2
- OR56B1 | c.231G>T p.M77I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100402544; called by muse, mutect2, varscan2
- OR56B1 | c.837G>T p.L279F | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0.12); catalogued as COSV100402545, COSV57722605; called by muse, mutect2
- OR5AS1 | c.797A>T p.Y266F | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV100546169; called by muse, mutect2, varscan2
- OR5D18 | c.344T>C p.L115S | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as COSV100450538; called by muse, mutect2, varscan2
- OR5T1 | c.511C>A p.H171N | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100478753; called by muse, mutect2, varscan2
- OR6C4 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.164); catalogued as rs1165785476, COSV101263127; called by muse, mutect2, varscan2
- PAK4 | c.1081G>T p.E361* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100426385, COSV58947531; called by muse, mutect2, varscan2
- PAK6 | c.1922G>T p.R641L | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53044455, COSV99544253; called by muse, mutect2, varscan2
- PARP4 | c.3367-1G>A p.X1123_splice | Splice Site (SNP) | VAF 10/78 reads (13%) | catalogued as COSV101131298; called by muse, mutect2, varscan2
- PAX4 | c.466C>T p.H156Y | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1390207636, COSV100489977; called by muse, mutect2, varscan2
- PCDHA11 | c.1116C>A p.S372R | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.767); catalogued as rs1188426625, COSV100247992, COSV56530443; called by muse, mutect2, varscan2
- PCDHA12 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.135); catalogued as rs1471783281, COSV56480984; called by muse, mutect2, varscan2
- PCDHB9 | c.2215G>A p.V739M | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.232); catalogued as COSV53381477; called by muse, mutect2, varscan2
- PCDHGA1 | c.694G>T p.V232L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.651); catalogued as COSV100966002, COSV65295341; called by muse, mutect2, varscan2
- PCDHGA10 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.035); catalogued as COSV99531923; called by muse, mutect2, varscan2
- PCDHGA3 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.036); catalogued as rs774225776, COSV99531919; called by muse, varscan2
- PCDHGC4 | c.985G>A p.A329T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.194); catalogued as COSV99338355; called by muse, mutect2, varscan2
- PCK1 | c.1742C>G p.S581C | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as COSV100100062, COSV60127429; called by muse, mutect2, varscan2
- PDE1C | c.730C>T p.L244F | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV100371269; called by muse, mutect2, varscan2
- PDE1C | c.98G>C p.G33A | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.995); catalogued as COSV100371273; called by muse, mutect2, varscan2
- PDE7A | c.1036G>C p.D346H (on ENST00000401827 / NM_001242318.3; = p.D320H on NM_002603.4) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as COSV101052609; called by muse, mutect2, varscan2
- PEG10 | c.382C>A p.R128S (on ENST00000482108 / NM_001040152.2; = p.R162S on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.988); catalogued as COSV101509855; called by muse, mutect2, varscan2
- PHF20L1 | c.1246C>T p.Q416* | Nonsense Mutation (SNP) | VAF 12/65 reads (18%) | catalogued as COSV99620444; called by muse, mutect2, varscan2
- PLCB3 | c.865G>T p.D289Y | Missense Mutation (SNP) | VAF 36/310 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99657137; called by muse, mutect2, varscan2
- PLEC | c.4237A>T p.I1413F (on ENST00000322810 / NM_201380.4; = p.I1303F on NM_000445.5) | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100511389; called by muse, mutect2, varscan2
- PLOD3 | c.1720G>T p.E574* | Nonsense Mutation (SNP) | VAF 13/89 reads (15%) | catalogued as COSV99777843; called by muse, mutect2, varscan2
- PLXNB3 | c.3329G>T p.S1110I | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100737160; called by muse, mutect2, varscan2
- POFUT1 | c.1091G>C p.R364P | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101003158; called by muse, mutect2, varscan2
- POGLUT3 | c.1359G>T p.Q453H | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.91); catalogued as COSV100052532; called by muse, mutect2, varscan2
- POLR1G | c.1372G>A p.G458R | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV50006063; called by muse, mutect2, varscan2
- POLR3B | c.3026A>G p.Y1009C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99943093; called by muse, mutect2, varscan2
- PPDPFL | c.135G>A p.G45= | Splice Region (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100293036; called by muse, mutect2
- PPFIA2 | c.1381C>A p.H461N | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV100331848; called by muse, mutect2, varscan2
- PPP1R12A | c.1970C>T p.S657F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.459); catalogued as COSV54109812; called by muse, mutect2, varscan2
- PPP1R21 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV99681707; called by muse, mutect2, varscan2
- PRAME | c.1050G>T p.Q350H | Missense Mutation (SNP) | VAF 40/565 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.234); catalogued as COSV101287019, COSV67161353; called by muse, mutect2
- PRG4 | c.1679C>A p.P560H | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as rs778552139, COSV100798107; called by muse, varscan2
- PRH1 | c.470A>C p.Q157P | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.702); catalogued as COSV101457479; called by muse, mutect2, varscan2
- PRH2 | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 16/182 reads (9%) | catalogued as COSV101113293; called by muse, mutect2
- PRKN | c.988G>T p.V330L | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.145); catalogued as rs749768565, COSV100627580, COSV58224511; called by muse, mutect2, varscan2
- PROX1 | c.344G>C p.G115A | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.214); catalogued as COSV99798743; called by muse, mutect2, varscan2
- PRRC2C | c.7507C>A p.L2503I (on ENST00000367742; = p.L2501I on NM_015172.4) | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100144742; called by muse, mutect2, varscan2
- PSMG2 | c.121A>T p.M41L | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.03); catalogued as COSV100042620; called by muse, mutect2, varscan2
- PTK7 | c.2206C>G p.Q736E | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as COSV100029883; called by muse, mutect2, varscan2
- PTPN5 | c.1171C>A p.H391N | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs778115185; called by muse, mutect2, varscan2
- RAB29 | c.60G>C p.K20N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99352913; called by muse, mutect2, varscan2
- RAB6C | c.749C>A p.P250H | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.099); catalogued as COSV101308469; called by muse, mutect2
- RAG1 | c.1990G>A p.D664N | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100200683; called by muse, mutect2, varscan2
- RAG1 | c.2798G>A p.G933E | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV100200686; called by muse, varscan2
- RBP3 | c.31G>T p.V11L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1406852831; called by muse, mutect2
- RELN | c.8336C>G p.S2779C | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100632628; called by muse, mutect2, varscan2
- RFPL2 | c.210A>C p.Q70H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV99964071; called by muse, mutect2, varscan2
- RHOXF1 | c.359G>A p.S120N | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.053); catalogued as rs1293096269, COSV99483757; called by muse, mutect2, varscan2
- RHOXF2B | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.626); catalogued as COSV101003947; called by muse, mutect2, varscan2
- RIC3 | c.160C>T p.H54Y | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV100111716; called by muse, mutect2, varscan2
- RIT2 | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.692); catalogued as COSV56294202, COSV56305991; called by muse, mutect2, varscan2
- RNF213 | c.13447A>T p.M4483L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100299810; called by muse, mutect2, varscan2
- RNF6 | c.1930A>T p.K644* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as COSV100644584; called by muse, mutect2, varscan2
- ROBO4 | c.1629C>A p.S543R | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100127332; called by muse, mutect2, varscan2
- ROPN1 | c.490C>T p.L164F | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51739440, COSV99481232; called by muse, mutect2
- RREB1 | c.4595G>T p.R1532L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.24); PolyPhen probably damaging (1); catalogued as COSV100619160; called by muse, mutect2, varscan2
- RRP12 | c.131G>T p.R44L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.129); catalogued as COSV100212938; called by muse, mutect2
- RSPH10B2 | c.576C>G p.G192= | Splice Region (SNP) | VAF 10/45 reads (22%) | catalogued as COSV99785955; called by mutect2, varscan2
- RTTN | c.4303G>C p.A1435P | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99731228; called by muse, mutect2
- RYR2 | c.7533C>A p.D2511E | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.014); catalogued as COSV100768308; called by muse, mutect2, varscan2
- RYR2 | c.9860A>G p.N3287S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV100768311; called by muse, mutect2
- RYR3 | c.2665T>A p.W889R | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202145001, COSV101212067; called by mutect2, varscan2
- S1PR5 | c.349G>T p.V117L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as COSV100330689; called by muse, mutect2, varscan2
- SAA2 | c.301A>T p.N101Y | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99879243; called by muse, mutect2, varscan2
- SAGE1 | c.1096G>T p.V366F | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100186749; called by muse, mutect2, varscan2
- SAMSN1 | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286396594, COSV99580777, COSV99582607; called by muse, mutect2
- SAP18 | c.120C>A p.H40Q (on ENST00000607003; = p.H59Q on NM_005870.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101229417; called by muse, mutect2
- SCUBE2 | c.3055A>G p.K1019E (on ENST00000649792 / NM_001367977.2; = p.K962E on NM_020974.3) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV100496355; called by muse, mutect2, varscan2
- SENP7 | c.1687G>T p.D563Y | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100052566; called by muse, mutect2, varscan2
- SERPING1 | c.296C>A p.T99N | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.109); catalogued as COSV99557843; called by muse, mutect2, varscan2
- SGSH | c.841G>T p.G281C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs541222703, COSV100413329; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SKIV2L | c.2912T>C p.L971P | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100514566; called by muse, mutect2, varscan2
- SLC17A4 | c.962C>A p.S321* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as COSV100930517; called by muse, mutect2, varscan2
- SLC22A2 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.806); catalogued as rs754756404, COSV100870933; called by muse, mutect2, varscan2
- SLC44A5 | c.52+1G>A p.X18_splice | Splice Site (SNP) | VAF 15/47 reads (32%) | catalogued as COSV100901315; called by muse, mutect2, varscan2
- SLC6A16 | c.684G>C p.M228I | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV100242582; called by muse, mutect2, varscan2
- SLC6A3 | c.1519G>T p.D507Y | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54363099, COSV99547896; called by muse, mutect2
- SLC8A1 | c.163T>G p.C55G | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60491767; called by muse, mutect2
- SLCO2A1 | c.755G>T p.R252L | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100188692, COSV60487005; called by muse, mutect2, varscan2
- SLITRK3 | c.2203C>A p.P735T | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV99578585; called by muse, mutect2, varscan2
- SMC5 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs756988546, COSV100746976; called by muse, mutect2, varscan2
- SMG8 | c.671A>C p.D224A | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.591); catalogued as COSV99958699; called by muse, mutect2, varscan2
- SNTB1 | c.788G>A p.R263K | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV101179801; called by muse, mutect2
- SNTG2 | c.797C>A p.T266N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV100421581; called by muse, mutect2
- SPACA1 | c.752G>A p.W251* | Nonsense Mutation (SNP) | VAF 13/74 reads (18%) | catalogued as rs781552345, COSV99389402; called by muse, mutect2, varscan2
- SPATA31D1 | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100782519, COSV100782654; called by muse, mutect2, varscan2
- SPCS1 | c.292dup p.S98Ffs*13 (on ENST00000233025; = p.S31Ffs*13 on NM_014041.5) | Frame Shift Ins (INS) | VAF 16/62 reads (26%) | catalogued as rs754517312; called by mutect2, pindel, varscan2
- SPHK1 | c.875C>A p.A292E (on ENST00000392496 / NM_001355139.2; = p.A306E on NM_021972.4) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as rs773839692, COSV100039175, COSV60063620; called by muse, mutect2, varscan2
- SPTA1 | c.1023C>G p.I341M | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100934409, COSV63757782; called by muse, mutect2, varscan2
- SPTA1 | c.96G>C p.L32F | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1221979324, COSV100934412, COSV100934689; called by muse, mutect2, varscan2
- STAM | c.1402G>A p.V468I | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.146); catalogued as rs781806131, COSV101097976; called by muse, mutect2, varscan2
- STARD3 | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1473199967, COSV100302695; called by muse, mutect2, varscan2
- STON1 | c.830C>G p.S277C | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as rs1262945647, COSV100561539; called by muse, mutect2, varscan2
- STYXL2 | c.3411C>G p.I1137M | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV99608644; called by muse, mutect2
- SULT1A1 | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs927153579, COSV100131606; called by muse, mutect2, varscan2
- SUN3 | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); catalogued as COSV52050951, COSV99813865; called by muse, mutect2, varscan2
- SUSD1 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 48/120 reads (40%) | catalogued as rs761847854, COSV100813187; called by muse, mutect2, varscan2
- SYNDIG1L | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100526402, COSV59046911; called by muse, mutect2, varscan2
- TAOK3 | c.2017G>T p.D673Y | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV101183437; called by muse, mutect2, varscan2
- TBC1D32 | c.738A>T p.L246F | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.066); catalogued as COSV99249627; called by muse, mutect2, varscan2
- TENT5B | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.142); catalogued as COSV100006489; called by muse, mutect2, varscan2
- TEX47 | c.651G>T p.L217F | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99787191; called by muse, mutect2, varscan2
- TFR2 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV99355447; called by muse, mutect2, varscan2
- TGIF2LX | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV99383195; called by muse, mutect2, varscan2
- TGM7 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV71773093; called by muse, mutect2, varscan2
- THG1L | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV51452875; called by muse, mutect2, varscan2
- THSD7A | c.3057C>A p.N1019K | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV70269718; called by muse, mutect2, varscan2
- THSD7B | c.3400G>T p.E1134* (on ENST00000272643; = p.E1132* on NM_001316349.2) | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as COSV55718927, COSV99745247; called by muse, mutect2, varscan2
- TLR8 | c.952C>G p.L318V (on ENST00000218032 / NM_138636.5; = p.L336V on NM_016610.4) | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99486813; called by muse, mutect2, varscan2
- TMEM132B | c.2368G>C p.E790Q | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.496); catalogued as rs746605414, COSV100168718, COSV54747217; called by muse, mutect2, varscan2
- TMEM168 | c.297T>G p.F99L | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.392); catalogued as COSV100454513; called by muse, mutect2
- TMEM176B | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58440427; called by muse, mutect2, varscan2
- TMX1 | c.13G>T p.G5W | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV100790051; called by muse, mutect2, varscan2
- TNNI3K | c.1841A>T p.Q614L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100435762; called by muse, mutect2, varscan2
- TP53BP2 | c.2997-2A>G p.X999_splice (on ENST00000343537 / NM_001031685.3; = p.X870_splice on NM_005426.2) | Splice Site (SNP) | VAF 9/71 reads (13%) | catalogued as COSV100636513; called by muse, mutect2, varscan2
- TPR | c.373A>T p.R125* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100823674; called by muse, mutect2, varscan2
- TREML4 | c.98G>T p.G33V | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100422832; called by muse, mutect2, varscan2
- TRIM22 | c.160A>G p.S54G | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV101181222; called by muse, mutect2, varscan2
- TRPA1 | c.1582C>A p.Q528K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.654); catalogued as COSV100083320; called by muse, mutect2
- TRPM1 | c.770G>A p.G257D | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs371005282, COSV99855452; called by muse, mutect2, varscan2
- TSPOAP1 | c.437T>C p.M146T | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV99270190; called by muse, mutect2
- TTC30A | c.1431_1432insT p.A478Cfs*6 | Frame Shift Ins (INS) | VAF 8/65 reads (12%) | catalogued as COSV100826141; called by mutect2, varscan2
- TTC30B | c.1431_1432insT p.A478Cfs*6 | Frame Shift Ins (INS) | VAF 19/167 reads (11%) | catalogued as COSV101282768; called by mutect2, pindel, varscan2
- TTN | c.96404C>T p.P32135L (on ENST00000591111; = p.P24711L on NM_003319.4) | Missense Mutation (SNP) | VAF 15/99 reads (15%) | PolyPhen probably damaging (0.999); catalogued as rs536357517, COSV100596665; called by muse, mutect2, varscan2
- TTN | c.44285C>A p.S14762Y (on ENST00000591111; = p.S7338Y on NM_003319.4) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | PolyPhen probably damaging (0.998); catalogued as rs774691242, COSV100596674; called by muse, mutect2, varscan2
- TTN | c.14545G>T p.E4849* (on ENST00000591111; = p.E3922* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/93 reads (17%) | catalogued as COSV100596681; called by muse, mutect2, varscan2
- TTN | c.13543G>A p.G4515S (on ENST00000591111; = p.G3588S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | PolyPhen possibly damaging (0.701); catalogued as COSV100596683; called by muse, mutect2, varscan2
- TXNL1 | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV99469449; called by muse, mutect2
- UBAP2 | c.1994C>T p.S665F | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV100670985; called by muse, mutect2
- UBQLN3 | c.147G>T p.E49D | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV100293384; called by muse, mutect2, varscan2
- UNC13A | c.2488G>A p.V830M | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as rs760950869, COSV53190047; called by muse, mutect2, varscan2
- UNC13C | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.902); catalogued as rs1359672529, COSV52843724; called by muse, mutect2
- UROC1 | c.473G>A p.S158N | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99330919; called by muse, mutect2
- USH2A | c.5426G>T p.G1809V | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as rs781101055, COSV100229859; called by muse, mutect2
- USP8 | c.684A>G p.P228= | Splice Region (SNP) | VAF 20/80 reads (25%) | catalogued as rs1461353902, COSV100208788; called by muse, mutect2, varscan2
- VPS13D | c.4258G>T p.D1420Y | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50670288; called by muse, mutect2, varscan2
- WDR90 | c.3805G>A p.G1269S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99552788; called by muse, mutect2, varscan2
- WNT10B | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.229); catalogued as COSV56406798; called by muse, mutect2
- XKR4 | c.436G>T p.G146W | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV100531080; called by muse, mutect2, varscan2
- XPNPEP2 | c.28C>A p.P10T | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.009); catalogued as COSV100941160; called by muse, mutect2, varscan2
- YLPM1 | c.5282T>C p.F1761S | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV99458702; called by muse, mutect2
- ZBTB20 | c.749G>T p.C250F (on ENST00000474710 / NM_001164342.2; = p.C177F on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.045); catalogued as COSV100612856; called by muse, mutect2, varscan2
- ZBTB40 | c.2752G>C p.D918H | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100988827, COSV100988874; called by muse, mutect2, varscan2
- ZCCHC14 | c.1736C>T p.S579L (on ENST00000268616; = p.S716L on NM_015144.3) | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.041); catalogued as rs751230705, COSV51891625; called by muse, mutect2, varscan2
- ZCWPW2 | c.413A>T p.H138L | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV101074562; called by muse, mutect2, varscan2
- ZFHX4 | c.4151G>A p.R1384K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51493556; called by muse, mutect2, varscan2
- ZFP82 | c.1000G>C p.G334R | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101088873, COSV101089213; called by muse, mutect2
- ZFYVE27 | c.131A>T p.Y44F | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.378); catalogued as COSV100519211; called by muse, mutect2, varscan2
- ZIC4 | c.714C>A p.F238L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.699); catalogued as COSV101267844, COSV67170598; called by muse, mutect2
- ZMYM5 | c.1455T>A p.N485K | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.038); catalogued as COSV100562564; called by muse, mutect2, varscan2
- ZNF112 | c.2377C>G p.Q793E (on ENST00000337401 / NM_001083335.2; = p.Q787E on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as COSV100495508; called by muse, mutect2
- ZNF182 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as COSV100526911; called by muse, mutect2, varscan2
- ZNF182 | c.349C>A p.L117M | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.052); catalogued as COSV100526914; called by muse, mutect2, varscan2
- ZNF248 | c.1177T>A p.S393T | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.311); catalogued as COSV100627477; called by muse, mutect2, varscan2
- ZNF329 | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs755020594, COSV100798677; called by muse, mutect2, varscan2
- ZNF385D | c.760C>A p.P254T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.023); catalogued as COSV55776414; called by muse, mutect2, varscan2
- ZNF536 | c.895C>A p.P299T | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100834753; called by muse, varscan2
- ZNF536 | c.981G>T p.E327D | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV100834754; called by muse, varscan2
- ZNF559-ZNF177 | c.860C>A p.T287N | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100605962; called by muse, mutect2, varscan2
- ZNF600 | c.874C>T p.H292Y | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100592915; called by muse, mutect2, varscan2
- ZNF630 | c.143G>C p.G48A | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as COSV99332193, COSV99332236; called by muse, mutect2
- ZNF671 | c.1514G>T p.R505M | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100234856; called by muse, mutect2, varscan2
- ZNF711 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.94); PolyPhen benign (0.015); catalogued as COSV99340699; called by muse, mutect2, varscan2
- ZNF789 | c.1084A>T p.I362F | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV100507810; called by muse, mutect2, varscan2
- ZNF804A | c.1324G>T p.E442* | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | catalogued as COSV100166602, COSV56468179; called by muse, mutect2, varscan2
- ZNF835 | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV73379248; called by muse, mutect2, varscan2
- ZNF835 | c.422C>A p.P141H | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.618); catalogued as rs1325323205, COSV101606272; called by muse, mutect2, varscan2
- ZNF92 | c.1746G>T p.E582D (on ENST00000328747 / NM_152626.4; = p.E513D on NM_007139.4) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100165682; called by muse, mutect2
- ZSCAN20 | c.1647A>T p.K549N | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100792497; called by muse, mutect2, varscan2
- ZSWIM4 | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99584535; called by muse, mutect2, varscan2
- AMY2A | c.661_662del p.D221Hfs*10 | Frame Shift Del (DEL) | VAF 34/264 reads (13%) | called by pindel, varscan2
- ARMC3 | c.1141del p.A381Qfs*3 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | called by mutect2, pindel, varscan2
- ASB4 | c.198G>C p.L66F | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2
- B3GLCT | c.571del p.A191Pfs*2 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | called by mutect2, pindel, varscan2
- BRINP1 | c.148C>A p.H50N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.932); called by muse, mutect2
- C12orf54 | c.275dup p.L94Vfs*63 | Frame Shift Ins (INS) | VAF 14/124 reads (11%) | called by mutect2, pindel, varscan2
- CCDC121 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH10 | c.1499del p.N500Mfs*7 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | called by pindel, varscan2
- CTNNA2 | c.954del p.D319Tfs*32 | Frame Shift Del (DEL) | VAF 39/144 reads (27%) | called by mutect2, pindel, varscan2
- CYP1B1 | c.995_998dup p.D333Efs*20 | Frame Shift Ins (INS) | VAF 11/35 reads (31%) | called by mutect2, pindel, varscan2
- DCHS1 | c.3520del p.Q1174Rfs*63 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | called by mutect2, pindel, varscan2
- ESRP2 | c.962_967del p.H321_G323delinsR (on ENST00000565858 / NM_001365264.1; = p.H311_G313delinsR on NM_024939.3 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel, varscan2
- FOXH1 | c.937dup p.V313Gfs*4 | Frame Shift Ins (INS) | VAF 18/145 reads (12%) | called by mutect2, pindel, varscan2
- GABRA3 | c.627dup p.G210Wfs*9 | Frame Shift Ins (INS) | VAF 28/65 reads (43%) | called by mutect2, pindel, varscan2
- HNRNPD | c.416del p.G139Vfs*13 | Frame Shift Del (DEL) | VAF 36/83 reads (43%) | called by mutect2, pindel, varscan2
- HOXA1 | c.175del p.V59Cfs*55 | Frame Shift Del (DEL) | VAF 17/85 reads (20%) | called by mutect2, pindel, varscan2
- HSPA6 | c.410dup p.Q139Pfs*16 | Frame Shift Ins (INS) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- IGHV3-23 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 16/102 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- IGKV1D-16 | c.65G>C p.C22S | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- IGKV3D-11 | c.221G>C p.R74T | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- LILRB3 | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LILRB3 | c.55A>T p.T19S | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- NBEA | c.1407del p.F469Lfs*8 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | called by mutect2, pindel
- NLRC3 | c.1690del p.A564Pfs*32 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | called by mutect2, varscan2
- NRXN3 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2G3 | c.803dup p.D269Gfs*? | Frame Shift Ins (INS) | VAF 5/41 reads (12%) | called by mutect2, pindel, varscan2
- PPP1R12C | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2
- PRDM9 | c.873C>A p.Y291* | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | called by muse, mutect2, varscan2
- PTPRA | c.493del p.I165Sfs*6 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel, varscan2
- SAMD3 | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.005); called by muse, mutect2
- STAC | c.310_316del p.G104Rfs*22 | Frame Shift Del (DEL) | VAF 25/80 reads (31%) | called by mutect2, pindel, varscan2
- TMC4 | c.166del p.V56Cfs*94 (on ENST00000617472 / NM_001145303.3; = p.V50Cfs*94 on NM_144686.4) | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | called by mutect2, pindel, varscan2
- WFIKKN2 | c.1594del p.E532Rfs*75 | Frame Shift Del (DEL) | VAF 11/56 reads (20%) | called by mutect2, pindel, varscan2
- XIRP2 | c.8298_8299delinsA p.L2767* (on ENST00000628543; = p.L2942* on NM_152381.6) | Frame Shift Del (DEL) | VAF 25/134 reads (19%) | called by pindel, varscan2*
- ABCC9 | c.1062A>G p.L354= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as rs1555114097, COSV99684677; ClinVar: likely benign; called by muse, mutect2, varscan2
- ACTR3B | c.942G>T p.P314= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs141764620, COSV99753638; called by mutect2, varscan2
- ADI1 | c.441G>T p.R147= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100537703; called by muse, mutect2, varscan2
- ADRA2A | c.378G>T p.A126= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs778256687, COSV54529415, COSV54529565; called by muse, mutect2, varscan2
- AFF3 | c.3642G>A p.Q1214= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- AKAP13 | c.7380C>T p.S2460= (on ENST00000394518 / NM_007200.5; = p.S2464= on NM_006738.6) | Silent (SNP) | VAF 97/301 reads (32%) | catalogued as COSV63449536; called by muse, mutect2, varscan2
- APOB | c.2256T>C p.N752= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV99263887; called by muse, mutect2, varscan2
- ARV1 | c.699C>G p.L233= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV100048294; called by muse, mutect2, varscan2
- ASTN2 | c.2031G>T p.S677= (on ENST00000313400 / NM_001365069.1; = p.S626= on NM_014010.5) | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as COSV100525083; called by muse, mutect2, varscan2
- ATP2B3 | c.657C>G p.V219= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV99683225; called by muse, mutect2, varscan2
- C1QL3 | c.393C>A p.A131= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV100126939; called by muse, mutect2, varscan2
- CABP7 | c.294G>T p.L98= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV99334687; called by muse, mutect2, varscan2
- CALB2 | c.585G>T p.L195= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as COSV100226100; called by muse, mutect2, varscan2
- CARMIL1 | c.3294A>T p.A1098= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV100277017; called by muse, mutect2, varscan2
- CEP135 | c.1035G>T p.G345= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV99954154; called by muse, mutect2, varscan2
- CFHR3 | c.375C>T p.T125= | Silent (SNP) | VAF 17/26 reads (65%) | catalogued as COSV100807429; called by muse, mutect2, varscan2
- CHAT | c.1995G>A p.E665= | Silent (SNP) | VAF 36/160 reads (23%) | catalogued as rs752896534, COSV100339818; called by muse, mutect2, varscan2
- CIITA | c.2385G>T p.R795= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV100161435; called by muse, mutect2
- CLCN4 | c.111G>A p.R37= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV101073679; called by muse, mutect2, varscan2
- CNGB3 | c.1824G>T p.V608= | Silent (SNP) | VAF 28/167 reads (17%) | catalogued as COSV100181338; called by muse, mutect2, varscan2
- CNTNAP2 | c.1680C>G p.P560= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as COSV100663248, COSV62145669; called by muse, varscan2
- CNTNAP5 | c.2133A>C p.G711= | Silent (SNP) | VAF 39/98 reads (40%) | catalogued as COSV101443118; called by muse, mutect2, varscan2
- COL22A1 | c.3735G>A p.E1245= | Silent (SNP) | VAF 22/180 reads (12%) | catalogued as rs1306692073, COSV100276587, COSV100281368; called by muse, mutect2, varscan2
- COL22A1 | c.852G>T p.V284= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100276588; called by muse, mutect2, varscan2
- CSMD2 | c.2799G>T p.G933= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV99586636; called by muse, mutect2, varscan2
- CUBN | c.2334C>A p.V778= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV100912122; called by muse, mutect2, varscan2
- DCAF12L1 | c.1065G>T p.S355= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV100948117, COSV64422566; called by muse, mutect2, varscan2
- DCBLD2 | c.2061G>T p.G687= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as rs200647911, COSV99504554; called by muse, mutect2, varscan2
- DDX60 | c.2547G>A p.E849= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV101190277; called by muse, mutect2, varscan2
- DENND4B | c.3477G>T p.L1159= | Silent (SNP) | VAF 8/113 reads (7%) | catalogued as COSV100768457; called by muse, mutect2
- DMD | c.8766C>T p.S2922= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs149776669, COSV58897982; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH5 | c.8319A>C p.L2773= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV99445646; called by muse, varscan2
- DPP10 | c.999G>T p.V333= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100059591; called by mutect2, varscan2
- DPYSL4 | c.1713C>G p.L571= | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as rs936760197, COSV100061894; called by muse, mutect2, varscan2
- EIF3K | c.630G>T p.V210= | Silent (SNP) | VAF 57/193 reads (30%) | catalogued as COSV99942907; called by muse, mutect2, varscan2
- EIF4EBP1 | c.177G>C p.L59= | Silent (SNP) | VAF 10/143 reads (7%) | catalogued as COSV100125874; called by muse, mutect2
- ELOVL3 | c.777C>A p.I259= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV100892744, COSV64175068; called by muse, mutect2
- EML5 | c.3387C>A p.T1129= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV100715105; called by muse, mutect2, varscan2
- ESR2 | c.688C>A p.R230= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs200629827, COSV99962863; called by muse, mutect2, varscan2
- EYS | c.678C>G p.G226= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV100675756, COSV104416995; called by muse, mutect2
- F5 | c.927T>A p.S309= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV100888947; called by muse, mutect2, varscan2
- FAM135B | c.1321C>T p.L441= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV52732319, COSV99419619; called by muse, mutect2, varscan2
- FARP1 | c.2850G>A p.Q950= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100129738; called by muse, mutect2
- FCGBP | c.1734G>T p.V578= | Silent (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- FRAS1 | c.7404G>T p.L2468= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV99348724; called by muse, mutect2, varscan2
- FRMD1 | c.441G>A p.V147= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV99349520; called by muse, mutect2, varscan2
- FRMD1 | c.231C>T p.R77= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs1441167271, COSV99349523; called by muse, mutect2, varscan2
- GABRB2 | c.1446T>A p.T482= (on ENST00000274547; = p.T444= on NM_000813.3) | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV99195686; called by muse, mutect2, varscan2
- GART | c.2742C>A p.I914= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV101111346; called by muse, mutect2, varscan2
- GNMT | c.681G>T p.V227= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV99769525; called by muse, mutect2, varscan2
- GRID2 | c.403C>A p.R135= | Silent (SNP) | VAF 36/72 reads (50%) | catalogued as rs780468524, COSV99937918; called by muse, mutect2, varscan2
- GRIN3A | c.831C>A p.T277= | Silent (SNP) | VAF 26/140 reads (19%) | catalogued as rs148925855, COSV100701381; called by muse, mutect2, varscan2
- GYPC | c.207G>T p.V69= | Silent (SNP) | VAF 28/160 reads (18%) | catalogued as COSV99391624; called by muse, mutect2, varscan2
- HEATR5A | c.2145A>C p.T715= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV101119636; called by muse, mutect2, varscan2
- HFM1 | c.3147T>C p.S1049= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV99645462; called by muse, mutect2, varscan2
- HTR1A | c.1146C>T p.G382= | Silent (SNP) | VAF 21/123 reads (17%) | catalogued as COSV60503747; called by muse, mutect2, varscan2
- IGF2R | c.1386G>A p.T462= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as rs370869979; called by muse, mutect2, varscan2
- IGFL2 | c.294T>A p.G98= (on ENST00000377693 / NM_001135113.2; = p.G109= on NM_001002915.2) | Silent (SNP) | VAF 16/112 reads (14%) | catalogued as COSV100890649; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1779C>T p.A593= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs368495685, COSV100145417; called by muse, mutect2, varscan2
- INKA1 | c.216A>C p.A72= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV100323527; called by muse, mutect2, varscan2
- INSR | c.3165G>C p.A1055= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as rs201445608, COSV100251573; called by muse, mutect2, varscan2
- IPO9 | c.2988G>A p.K996= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as COSV100843343; called by muse, mutect2, varscan2
- ITGA8 | c.2544C>A p.A848= | Silent (SNP) | VAF 7/106 reads (7%) | catalogued as COSV100958917, COSV65226779; called by muse, mutect2
- JARID2 | c.2899C>T p.L967= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV100521403; called by muse, mutect2, varscan2
- KAT14 | c.1368A>G p.K456= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV100890038; called by muse, mutect2, varscan2
- KIAA1210 | c.78T>A p.A26= | Silent (SNP) | VAF 32/56 reads (57%) | catalogued as COSV101273938; called by muse, mutect2, varscan2
- KIF2B | c.360C>G p.P120= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as COSV99274776, COSV99275894; called by muse, mutect2, varscan2
- KIF2B | c.1191G>T p.V397= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as COSV52128847; called by muse, mutect2
- KIRREL3 | c.2331C>T p.H777= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs779698362, COSV101375171, COSV101375186; called by muse, varscan2
- KLHDC7A | c.2274C>A p.G758= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as COSV101272732; called by muse, mutect2
- KNL1 | c.3501C>T p.L1167= (on ENST00000346991 / NM_170589.5; = p.L1141= on NM_144508.5) | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV61158426; called by muse, mutect2, varscan2
- KRTAP13-2 | c.141G>A p.Q47= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as rs61748319, COSV101299621; called by muse, mutect2, varscan2
- MAGEA6 | c.831C>A p.A277= | Silent (SNP) | VAF 69/153 reads (45%) | catalogued as rs1556836880, COSV100262687; called by muse, mutect2, varscan2
- MAP2 | c.1923A>T p.A641= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV99558140; called by muse, mutect2, varscan2
- MAP2 | c.2115G>A p.P705= | Silent (SNP) | VAF 26/142 reads (18%) | catalogued as rs376603789; called by muse, mutect2, varscan2
- MAP7D3 | c.522T>C p.S174= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100286197; called by muse, mutect2, varscan2
- MARCHF7 | c.684A>C p.S228= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs368594553; called by muse, mutect2, varscan2
- MAT2B | c.214C>T p.L72= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV99796538; called by muse, mutect2, varscan2
- MPLKIP | c.378T>C p.R126= | Silent (SNP) | VAF 22/119 reads (18%) | catalogued as COSV100000185; called by muse, mutect2, varscan2
- MTHFR | c.138G>T p.R46= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100411636; called by muse, mutect2, varscan2
- MTMR4 | c.2610G>A p.R870= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV100050805; called by muse, mutect2, varscan2
- MUC5B | c.12918C>A p.T4306= | Silent (SNP) | VAF 12/224 reads (5%) | catalogued as COSV101500056; called by muse, mutect2
- MYH7 | c.1926G>T p.S642= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV100805741; called by muse, mutect2, varscan2
- NCKAP5 | c.3834C>T p.F1278= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as rs376005925; called by muse, mutect2, varscan2
- NRG4 | c.204G>A p.L68= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as COSV101204843; called by muse, varscan2
- NWD1 | c.3948C>T p.I1316= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs749249652, COSV100341828; called by muse, mutect2, varscan2
- OLFML2B | c.75C>T p.L25= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV99668075; called by muse, mutect2
- OR10R2 | c.213G>T p.L71= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV100936764; called by muse, mutect2, varscan2
- OR14A16 | c.301T>C p.L101= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV100713704; called by muse, mutect2, varscan2
- OR14C36 | c.123C>T p.I41= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV58603175; called by muse, mutect2, varscan2
- OR2T1 | c.660C>A p.I220= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV63543135; called by muse, mutect2, varscan2
- OR4D10 | c.364C>A p.R122= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV101596994, COSV73259977; called by muse, mutect2, varscan2
- OR4D9 | c.321G>A p.L107= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV100259719; called by muse, mutect2
- OR51I2 | c.510A>G p.R170= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV100413311; called by muse, mutect2, varscan2
- OR5D16 | c.54C>T p.G18= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV101003856; called by muse, mutect2, varscan2
- PCDHA9 | c.2025G>A p.A675= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs782515896, COSV100969107; called by muse, mutect2, varscan2
- PCDHGA3 | c.858G>A p.G286= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99531447; called by muse, varscan2
- PDHA2 | c.327G>A p.S109= | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as rs371275508; called by muse, mutect2, varscan2
- PEG10 | c.381C>A p.G127= (on ENST00000482108 / NM_001040152.2; = p.G161= on NM_015068.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV101509854; called by muse, mutect2, varscan2
- PIP5K1C | c.1899G>A p.A633= | Silent (SNP) | VAF 42/113 reads (37%) | catalogued as rs780522460, COSV100095035; called by muse, mutect2, varscan2
- PISD | c.1161C>G p.P387= (on ENST00000439502 / NM_001326412.1; = p.P353= on NM_014338.3) | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99837181, COSV99837187; called by muse, mutect2, varscan2
- PLEKHM1 | c.768G>A p.T256= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs753881253, COSV101378680; called by muse, mutect2
- PLG | c.741C>A p.T247= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99804298; called by muse, mutect2
- PLXNA4 | c.4425C>T p.D1475= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs376463343; called by muse, mutect2, varscan2
- PMM1 | c.582G>A p.E194= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV99348042; called by muse, mutect2, varscan2
- POGZ | c.2481C>T p.G827= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as rs202037269, COSV55043799; called by muse, mutect2
- PRKG1 | c.1027C>T p.L343= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV64774750, COSV64775177; called by muse, mutect2, varscan2
- PROX1 | c.522G>T p.R174= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV54783552, COSV99798746; called by muse, mutect2, varscan2
- PRUNE2 | c.2265C>A p.P755= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100944255; called by muse, mutect2, varscan2
- RDH13 | c.816A>T p.T272= (on ENST00000415061 / NM_001145971.2; = p.T201= on NM_138412.4) | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as rs776298884, COSV99401389; called by muse, mutect2
- REG3A | c.114C>A p.I38= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV59410233; called by muse, mutect2, varscan2
- RHBDF1 | c.1236C>T p.F412= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as rs774261543, COSV51954780; called by muse, mutect2, varscan2
- RNF123 | c.3123C>T p.F1041= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV57539246; called by muse, mutect2, varscan2
- RPE65 | c.1260A>G p.Q420= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV99253634; called by muse, mutect2, varscan2
- RTN1 | c.960C>T p.V320= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs796816944, COSV99954756; called by muse, mutect2, varscan2
- SALL1 | c.1314G>T p.A438= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV51752735, COSV99171607; called by muse, mutect2, varscan2
- SDC3 | c.786G>T p.P262= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV100232126; called by muse, mutect2, varscan2
- SEMA4C | c.2283A>G p.P761= | Silent (SNP) | VAF 35/107 reads (33%) | catalogued as COSV100560755; called by muse, mutect2, varscan2
- SENP7 | c.1686G>C p.V562= | Silent (SNP) | VAF 25/169 reads (15%) | catalogued as COSV100052569; called by muse, mutect2, varscan2
- SERPING1 | c.297C>A p.T99= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV99557844; called by muse, mutect2, varscan2
- SGSM1 | c.2841C>T p.D947= (on ENST00000400359 / NM_001039948.4; = p.D886= on NM_133454.3) | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as rs944156704, COSV100771851; called by muse, mutect2
- SHROOM3 | c.903G>A p.Q301= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV99933626; called by muse, mutect2, varscan2
- SLC13A2 | c.138G>C p.A46= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV100120147; called by muse, mutect2
- SLC30A9 | c.1104T>A p.R368= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV100047987; called by muse, mutect2, varscan2
- SLC35F1 | c.567C>T p.I189= | Silent (SNP) | VAF 25/208 reads (12%) | catalogued as COSV64503559; called by muse, mutect2, varscan2
- SLC7A11 | c.1125G>A p.L375= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs138007034; called by muse, mutect2, varscan2
- SLITRK2 | c.261C>T p.N87= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV100157381; called by muse, mutect2, varscan2
- SNAP91 | c.1488T>C p.F496= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV99534528; called by muse, varscan2
- SORCS1 | c.2544C>T p.L848= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99543789; called by muse, mutect2
- SPPL2B | c.1749C>T p.S583= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV101476101; called by muse, mutect2, varscan2
- SRSF7 | c.435C>G p.R145= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as rs751001557, COSV100492540; called by muse, mutect2, varscan2
- STAMBPL1 | c.138C>T p.I46= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV100905078; called by muse, mutect2, varscan2
- STK39 | c.1068C>T p.D356= | Silent (SNP) | VAF 26/126 reads (21%) | catalogued as rs760592031, COSV100596266; called by muse, mutect2, varscan2
- TADA1 | c.192G>T p.L64= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100902290; called by muse, mutect2
- TBX18 | c.1143C>T p.G381= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs766116934, COSV100858442; called by muse, mutect2, varscan2
- TENM3 | c.5943C>T p.N1981= | Silent (SNP) | VAF 84/174 reads (48%) | catalogued as rs760477721, COSV101304917; called by muse, mutect2, varscan2
- THSD7A | c.447G>T p.G149= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV101448561; called by muse, mutect2, varscan2
- TIMELESS | c.1143C>T p.A381= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV99973696; called by muse, mutect2, varscan2
- TMEM199 | c.357C>G p.T119= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV99134705; called by muse, mutect2, varscan2
- TNR | c.1791C>T p.P597= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV54898829; called by muse, mutect2, varscan2
- TP53 | c.744G>T p.R248= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV52782654, COSV53050697, COSV53372256; called by muse, varscan2
- TP73 | c.990C>T p.F330= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100600980; called by muse, mutect2, varscan2
- TRANK1 | c.8208A>G p.P2736= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV100081718; called by muse, mutect2, varscan2
- TRAV3 | c.276C>A p.S92= | Silent (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- TTC31 | c.924G>T p.L308= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as COSV99281949; called by muse, mutect2, varscan2
- TTN | c.69336T>C p.N23112= (on ENST00000591111; = p.N15688= on NM_003319.4) | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV100596668; called by muse, mutect2, varscan2
- TTN | c.16245C>T p.F5415= (on ENST00000591111; = p.F4488= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100596679; called by muse, mutect2, varscan2
- UBE2Q1 | c.948A>C p.L316= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV52725876, COSV99427253; called by muse, mutect2, varscan2
- VN1R5 | c.414C>A p.L138= | Silent (SNP) | VAF 11/91 reads (12%) | called by muse, mutect2, varscan2
- WDR91 | c.1320C>A p.I440= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV100615577; called by muse, mutect2, varscan2
- YEATS2 | c.495C>G p.L165= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as rs367573229; called by muse, mutect2, varscan2
- ZC3H4 | c.525G>T p.T175= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV99451776; called by mutect2, varscan2
- ZFHX4 | c.2430C>T p.H810= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs1246611426, COSV99257287; called by muse, mutect2, varscan2
- ZMAT4 | c.204C>A p.A68= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV99908704; called by muse, mutect2, varscan2
- ZNF384 | c.1371G>A p.P457= (on ENST00000361959; = p.P396= on NM_133476.5) | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs201845505, COSV100158215; called by muse, mutect2, varscan2
- ZNF480 | c.1473C>G p.V491= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV100574051, COSV100574265; called by muse, mutect2, varscan2
- ZNF536 | c.894G>A p.K298= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV62829355; called by muse, varscan2
- AL353804.6 | chrX:73826344 G>C | 3'Flank (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- ARMC8 | c.1134+20G>T | Intron (SNP) | VAF 10/70 reads (14%) | catalogued as COSV100627510, COSV61769887; called by muse, mutect2, varscan2
- BTN2A3P | n.1448-399A>T | Intron (SNP) | VAF 40/92 reads (43%) | called by muse, mutect2, varscan2
- C22orf15 | c.251-25T>C | Intron (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- CD99 | c.67+432C>T | Intron (SNP) | VAF 5/23 reads (22%) | catalogued as COSV101152890; called by muse, mutect2
- GK5 | c.816+183G>T | Intron (SNP) | VAF 4/18 reads (22%) | catalogued as COSV101242101; called by muse, mutect2
- GLYATL1 | c.-150G>T | 5'UTR (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100265167, COSV55610284; called by muse, mutect2
- HERC2P3 | n.592T>C | RNA (SNP) | VAF 21/59 reads (36%) | called by muse, mutect2, varscan2
- HERC2P3 | n.145G>A | RNA (SNP) | VAF 6/40 reads (15%) | called by mutect2, varscan2
- LDLRAD4 | c.-2G>A | 5'UTR (SNP) | VAF 24/107 reads (22%) | catalogued as COSV100761989; called by muse, mutect2, varscan2
- MIR1246 | n.38C>T | RNA (SNP) | VAF 35/166 reads (21%) | catalogued as rs753015179; called by muse, mutect2, varscan2
- MTRNR2L6 | chr7:142671057 T>A | 3'Flank (SNP) | VAF 13/133 reads (10%) | called by muse, mutect2
- NTRK3 | c.1586-40492G>T | Intron (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100445667; called by muse, mutect2, varscan2
- PHKB | c.2427+971G>A | Intron (SNP) | VAF 5/39 reads (13%) | catalogued as COSV100065691; called by muse, mutect2, varscan2
- RAB34 | c.-2G>A | 5'UTR (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99973893; called by muse, mutect2
- SNORD115-30 | n.38G>T | RNA (SNP) | VAF 91/252 reads (36%) | called by muse, mutect2, varscan2
- SNORD115-32 | n.53A>G | RNA (SNP) | VAF 107/298 reads (36%) | catalogued as rs1002677479; called by muse, mutect2, varscan2
- ZNF271P | n.1470G>C | RNA (SNP) | VAF 14/101 reads (14%) | called by muse, mutect2, varscan2
